Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A43E, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A43E-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: [REDACTED]

PAT TYPE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

1. Distal esophagus proximal stomach. 2 Appendix. 3. Cervical esophageal margin. Past medical history of esophageal cancer. GERD. Hypertension. Operative Procedure: Transhiatal esophagectomy.

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Distal esophagus proximal stomach". Received in a medium container of formalin is a previously opened transhiatal esophagectomy specimen consisting of distal esophagus, 7.2 cm in length, 2.3 to 4.7 cm in internal circumference, proximal stomach, 4.0 cm in length, 9.5 cm in internal circumference and attached perigastric adipose tissue. Specimen is notable for a 7.0 x 4.0 x 4.0 cm circumferential tan, multilobulated, polypoid mass arising from nodular mucosa, 3.5 cm above the gastroesophageal junction, measurement from short lesion, 3.0 cm from the proximal staple line and 4.5 cm from the distal gastric resection margin. The mass has tan, solid cut surfaces and grossly does not appear to invade into the underlying wall. The uninvolved esophageal and gastric mucosa are unremarkable. The perigastric adipose tissue is dissected and palpated to reveal multiple possible lymph nodes, ranging from 0.2 to 1.0 cm in greatest dimension.

1A-D. One continuous longitudinal section through tumor submitted from proximal to distal to include esophageal and gastric mucosa, proximal ends inked orange.

1E-G. Mass to include blue inked radial soft tissue margins.

1H-J. Tumor.

1K-M. Lymph node candidates submitted intact.

1N and O. Each contain one lymph node candidate. Bisected. Fat retained.

2. "Cervical esophageal margin". Received in a tall small container of formalin is a 0.8 cm in length, 1.2 cm in diameter stapled cuff of esophagus. The staple line is shaved and the specimen is submitted en face in cassette 2A. Staple line retained.

3. "Appendix". Received in a tall small container is a 5.5 cm in length, 0.8 cm in diameter appendix with attached mesoappendix. The serosa is a tan-pink, smooth, glistening with arborizing vessels. The appendix is serially cross sectioned to reveal a fatty wall, 0.3 cm in greatest thickness surrounding a pinpoint lumen.

3A. Standard sections of appendix.

ICD-O-3

adenocarcinoma, NOS

8140/3

Site: esophagus, distal third

C15.5

8-20-12
ED

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

SEX: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE:

REQ DOC: [REDACTED]

PROCEDURE: SPMI

VERIFIED BY: [REDACTED]

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA, CARCINOMA

LOCATION: Distal esophagus

SIZE: 7.0 cm including both polypoid high-grade dysplasia and carcinoma.

HAS IT BEEN TREATED PREOPERATIVE WITH CHEMO/RADIATION THERAPY?: No

TYPE OF CARCINOMA: Adenocarcinoma arising in Barrett's mucosa

DEPTH OF INVASION: Superficial submucosa

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/10

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

pT1b N0

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1-2. Distal esophagus, resection: Invasive adenocarcinoma extending into superficial submucosa arising from extensive Barrett's high-grade dysplasia. Margins free. Ten lymph nodes negative for carcinoma. Please see TEMPLATE for details. See COMMENT.

3. Appendix, resection: No significant abnormality.

COMMENT:

=====

Most of the carcinoma is differentiated and confined to the mucosa. There is one focus of undifferentiated carcinoma that extends into the superficial submucosa.

[REDACTED]

Source: NCI Genomic Data Commons file da734c0f-578e-41d3-88ec-0a78d22be9b4 (TCGA-L5-A43E.362C7FE6-C8A0-4D38-88A7-B603AFC7AC83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).